Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA6P, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA6P-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender:

F

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

History of bladder cancer for TURBT.

Specimens Submitted:

1: Right lateral wall tumor in

2: Right lateral wall tumor

3: Right lateral wall deep

DIAGNOSIS:

1. Right lateral wall tumor in

Tumor Type:

Urothelial carcinoma with mixed histologic features, including: NoS and micropapillary types

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

Papillary and flat

Local Invasion:

Muscularis propria

Vascular Invasion:

Identified

Pw TSS, TCGA tumor = pure urothelial.

*ICD-O3
Carcinoma, urothelial NOS 8120/3
Site: Bladder lateral wall
C67.2
JW 4/30/14*

2. Right lateral wall tumor:

Tumor Type:

Urothelial carcinoma with mixed histologic features, including: NoS and micropapillary types

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

Papillary and flat

Local Invasion:

Muscularis propria

Vascular Invasion:

Identified

3. Right lateral wall deep:

Tumor Type:

Invasive urothelial carcinoma, NOS

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

Papillary and flat

Local Invasion:

Muscularis propria

Vascular Invasion:

Identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1). The specimen is received in _____, labeled "right lateral wall tumor", and consists of multiple pieces of tan soft tissue ranging from 0.2 to 1.0 cm. The specimen is entirely submitted one cassette(s). TPS taken.
- 2). The specimen is received in formalin, labeled "right lateral wall tumor", and consists of multiple pieces of tan soft tissue ranging from 0.2 to 1.1 cm. The specimen is entirely submitted two cassette(s).
- 3). The specimen is received in formalin, labeled "right lateral wall deep", and consists of multiple pieces of tan soft tissue ranging from 0.2 to 1.0 cm. The specimen is entirely submitted one cassette(s).

Summary of Sections:

Part 1: Right lateral wall tumor in

Blocks	Block Designation	PCs
1	{not entered}	6

Part 2: Right lateral wall tumor

Blocks	Block Designation	PCs
2	{not entered}	12

Part 3: Right lateral wall deep

Blocks	Block Designation	PCs
1	{not entered}	6

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file a5cd5004-7905-41fe-958f-b8272f5b66f1 (TCGA-DK-AA6P.2D499EC2-59F5-462D-A60C-BD19B4BE8E46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).